Gene-level copy-number profile of tumor specimen TCGA-13-1482-01A from TCGA case TCGA-13-1482, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 52.5 years (19,178 days).
Specimen TCGA-13-1482-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.576a7db4-0c37-4d05-a4ed-cee6c88bc73c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1482-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3dfa0a7d-3be8-47cd-86ab-9216982d2eed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,005; copy number 2: 34,263; copy number 3: 7,617; copy number 4: 910; copy number 5: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1482-01A-01D-0472-01): tumor purity 0.86, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:133,034,607–134,735,129, 20 genes, copy number 5: AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2.

Autosomal genes at a single copy (total copy number 1): 17,005. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
